CCDI case PBCKYZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c3c8c648-9439-4396-aaf2-c169bcd350b8

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.5 years (3,463 days).

Biospecimens (3 samples)
- Sample 0DUETJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUETU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUEUB: Tissue type: Tumor; Specimen type: Solid Tissue.
